Gene-level copy-number profile of tumor specimen TCGA-SG-A6Z7-01A from TCGA case TCGA-SG-A6Z7, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 44.3 years (16,188 days).
Specimen TCGA-SG-A6Z7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.7f417787-01ec-4cdc-aa67-a833c3fcebcb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SG-A6Z7-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c8ffee78-9054-4200-ba9a-eb2e7caba551

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 26; copy number 2: 7,537; copy number 3: 26,517; copy number 4: 20,009; copy number 5: 1,616; copy number 6: 2,297; copy number 7: 409; copy number 8: 320; copy number 9: 348; copy number 10: 182; copy number 11: 200; copy number 12: 108; copy number 13: 70; copy number 14: 4; copy number 15: 14; copy number 16: 22; copy number 18: 10; copy number 19: 5; copy number 20: 13; copy number 21: 15; copy number 22: 2; copy number 24: 14; copy number 25: 10; copy number 28: 3; copy number 30: 7; copy number 31: 1; copy number 32: 1; copy number 34: 5; copy number 44: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SG-A6Z7-01A-12D-A32H-01): tumor purity 0.93, ploidy 3.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:117,026,698–117,027,039, 1 gene: PTMAP8.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr17:31,094,927–31,382,116, 1 gene (within-gene range 0–2): NF1.
- chr17:31,272,013–31,575,659, 16 genes: OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,775 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–147,842,359, 28 genes, copy number 8: AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1.
- chr1:151,197,949–153,992,155, 169 genes, copy number 8–15 (broad region; genes not listed).
- chr1:153,995,632–154,040,022, 2 genes, copy number 10: AL358472.1, RNU6-179P.
- chr1:155,659,443–156,007,070, 17 genes, copy number 11 (within-gene range 4–11): YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1.
- chr1:169,915,004–173,612,772, 77 genes, copy number 9–24 (within-gene range 4–24) (broad region; genes not listed).
- chr1:175,044,626–175,335,459, 6 genes, copy number 15: ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1.
- chr2:198,882,573–199,110,088, 2 genes, copy number 11 (within-gene range 3–11): AC020718.1, AC018717.1.
- chr6:65,788,417–67,625,464, 10 genes, copy number 9: SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA.
- chr6:115,931,149–116,597,675, 21 genes, copy number 8: FRK, AL357141.1, TPI1P3, NT5DC1, COL10A1, NIP7P3, AL050331.2, TSPYL4, DSE, AL050331.1, TSPYL1, Z84488.1, CBX3P9, KRT18P22, CALHM6-AS1, CALHM6, AL445224.1, TRAPPC3L, CALHM5, CALHM4, RWDD1.
- chr6:117,318,211–118,454,992, 11 genes, copy number 8 (within-gene range 2–8): AL132671.2, RAP1BP3, AL132671.1, DCBLD1, RNU6-253P, GOPC, NEPNP, NUS1, SLC35F1, AL450405.1, AL589993.1.
- chr6:118,501,430–118,561,716, 2 genes, copy number 8 (within-gene range 2–8): BRD7P3, PLN.
- chr6:122,779,716–124,825,640, 11 genes, copy number 7–9 (within-gene range 2–9): FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1.
- chr7:123,113,531–123,230,741, 2 genes, copy number 22 (within-gene range 3–22): SLC13A1, LYPLA1P1.
- chr7:130,790,208–131,558,217, 19 genes, copy number 7–13: AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1.
- chr7:132,123,332–133,170,514, 12 genes, copy number 13–16 (within-gene range 3–16): PLXNA4, AC018643.1, AC011625.1, FLJ40288, AC009365.1, AC009365.2, CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7.
- chr7:133,290,881–133,315,413, 2 genes, copy number 16: MIR6133, AC083875.1.
- chr8:55,449,509–103,002,424, 770 genes, copy number 7–13 (within-gene range 6–13) (broad region; genes not listed).
- chr8:117,055,818–130,017,129, 195 genes, copy number 7–10 (broad region; genes not listed).
- chr8:130,069,541–130,084,768, 2 genes, copy number 7: RNU6-1255P, ASAP1-IT2.
- chr8:138,588,235–144,475,849, 181 genes, copy number 7–8 (broad region; genes not listed).
- chr10:126,272,818–126,421,879, 3 genes, copy number 7–10: SAR1AP2, AL589787.2, LINC00601.
- chr10:126,425,930–126,460,957, 1 gene, copy number 7: AL589787.1.
- chr12:57,243,453–57,797,554, 38 genes, copy number 12 (within-gene range 6–12): STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3.
- chr12:58,087,892–62,279,150, 36 genes, copy number 8–30: LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1.
- chr12:62,260,359–62,260,454, 1 gene, copy number 13: MIR6125.
- chr12:65,758,020–66,066,338, 9 genes, copy number 18 (within-gene range 3–18): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362.
- chr12:66,302,493–67,069,162, 2 genes, copy number 20–32 (within-gene range 3–32): HELB, GRIP1.
- chr12:66,950,754–68,487,863, 30 genes, copy number 20–34: AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2.
- chr12:68,686,951–68,971,570, 12 genes, copy number 44 (within-gene range 2–44): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,946,543–69,947,081, 1 gene, copy number 11: AC078922.1.
- chr12:70,239,114–70,434,292, 4 genes, copy number 7–19 (within-gene range 6–19): AC092881.2, CNOT2, AC092881.1, KCNMB4.
- chr12:70,906,917–71,927,248, 20 genes, copy number 7–16: Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:72,087,266–72,670,758, 4 genes, copy number 13–24 (within-gene range 3–24): TRHDE, TRHDE-AS1, H3P35, CHCHD3P2.
- chr12:73,159,190–73,208,317, 2 genes, copy number 16: LINC02444, AC090503.1.
- chr12:73,820,315–74,402,600, 4 genes, copy number 9–20 (within-gene range 3–20): LINC02882, AC136188.1, LINC02394, AC090502.3.
- chr12:85,036,314–85,568,239, 4 genes, copy number 12–31 (within-gene range 3–31): LRRIQ1, ALX1, LINC02820, AC126471.1.
- chr12:85,874,295–86,838,904, 4 genes, copy number 13–28 (within-gene range 2–28): NTS, MGAT4C, AC016993.1, AC139697.1.
- chr12:89,500,093–90,100,763, 12 genes, copy number 8–10 (within-gene range 3–10): CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P.
- chr12:90,107,739–91,005,026, 9 genes, copy number 8–25: AC126178.1, LINC02392, LINC02822, AC084365.1, AC112481.2, AC112481.1, CCER1, LINC00615, EPYC.
- chr21:15,614,283–17,707,455, 34 genes, copy number 7–12: RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
